Somatic mutation profile of tumor specimen 0DWVG6 from CCDI case PBCPLN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 16.3 years (5,940 days).
Specimen 0DWVG6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc93476c-6931-4d87-94fc-e5716f92f2ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWVEK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c1f202d-d80e-4bd0-9b6c-f0f4037eae53

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 3'UTR 2, Splice Site 2, Intron 1, 5'UTR 1, 5'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC1H1 | c.13771C>T p.R4591C | Missense Mutation (SNP) | VAF 55/336 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.91); catalogued as rs765362140, COSV100795405; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9B | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 8/205 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68276659; called by muse, mutect2
- PARP10 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs374084353; called by muse, mutect2, varscan2
- PLXNB3 | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.67); catalogued as rs782508777, COSV62797617; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2248+1G>A p.X750_splice (on ENST00000343619 / NM_001378531.1; = p.X744_splice on NM_005177.5 and 6 other RefSeq transcripts) | Splice Site (SNP) | VAF 123/281 reads (44%) | called by muse, mutect2, varscan2
- CDKAL1 | c.639-2A>G p.X213_splice | Splice Site (SNP) | VAF 42/220 reads (19%) | called by muse, mutect2, varscan2
- GSTA2 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 47/407 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TARS2 | c.851C>A p.T284K | Missense Mutation (SNP) | VAF 21/598 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2
- A4GALT | c.621G>T p.V207= | Silent (SNP) | VAF 63/265 reads (24%) | called by muse, mutect2, varscan2
- CBX4 | c.*68G>T | 3'UTR (SNP) | VAF 55/129 reads (43%) | catalogued as COSV99490201; called by muse, mutect2, varscan2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 16/158 reads (10%) | catalogued as rs1415560984; called by mutect2, varscan2
- POTEC | chr18:14543194 C>T | 5'Flank (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 16/139 reads (12%) | called by muse, varscan2
- XIRP2 | c.*871A>C | 3'UTR (SNP) | VAF 26/326 reads (8%) | called by muse, mutect2
